Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAGI, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAGI-05A (Additional - New Primary).

ICD-O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.4
JN 3/4/14

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 3.7 cm; invasion in rete testis and tunica albuginea.
Epididymis free of tumor; surgical margin of spermatic cord free of tumor.
In : nonseminoma in right testis (see case).

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

2nd Primary.

Source: NCI Genomic Data Commons file 0c09b7e7-952a-42a9-ac10-a7243d9420af (TCGA-2G-AAGI.4A342E88-7B58-420C-AEB7-8209F087E9F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).